Somatic mutation profile of tumor specimen TCGA-DB-5281-01A (aliquot TCGA-DB-5281-01A-01D-1468-08) from TCGA case TCGA-DB-5281, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 61.2 years (22,342 days).
Specimen TCGA-DB-5281-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 50e06a01-7860-4b15-a848-3a1a655665e6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DB-5281-10A (Blood Derived Normal), aliquot TCGA-DB-5281-10A-01D-1468-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4aad8add-21d1-49f4-bd4c-cae16d5005a5

The open-access MAF lists 53 somatic variants for this specimen: 42 protein-altering or splice-affecting, 9 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 9, Nonsense Mutation 4, Splice Site 3, Frame Shift Del 3, Intron 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 31/74 reads (42%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- NEK8 | c.1795C>T p.R599* | Nonsense Mutation (SNP) | VAF 28/153 reads (18%) | catalogued as rs375661404, CM135090, COSV52046500; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 44/98 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.96+1_96+6del p.X32_splice | Splice Site (DEL) | VAF 22/54 reads (41%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- ACSS3 | c.1928C>T p.P643L | Missense Mutation (SNP) | VAF 23/152 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1331201644, COSV54089239; called by muse, mutect2, varscan2
- AICDA | c.295C>T p.R99* | Nonsense Mutation (SNP) | VAF 16/83 reads (19%) | catalogued as rs757606065, COSV57563386; called by muse, mutect2, varscan2
- ATRX | c.665G>A p.W222* | Nonsense Mutation (SNP) | VAF 87/100 reads (87%) | catalogued as CM970155, COSV64874976; called by muse, mutect2, varscan2
- BEND2 | c.200G>A p.G67D | Missense Mutation (SNP) | VAF 44/51 reads (86%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV66215616; called by muse, mutect2, varscan2
- C3orf18 | c.376G>T p.A126S | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.879); catalogued as COSV61746809; called by muse, mutect2, varscan2
- C8orf74 | c.797C>T p.P266L | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.68); PolyPhen benign (0.028); catalogued as rs546522798, COSV58753984; called by muse, mutect2, varscan2
- CCNA1 | c.1210T>C p.W404R | Missense Mutation (SNP) | VAF 44/120 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55220988; called by muse, mutect2, varscan2
- CD44 | c.1547C>T p.S516L | Missense Mutation (SNP) | VAF 35/184 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs572774966, COSV53528800; called by muse, mutect2, varscan2
- CHD5 | c.3973C>T p.R1325W | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs978646000, COSV52412495; called by muse, mutect2, varscan2
- DCTN1 | c.1793G>A p.R598Q | Missense Mutation (SNP) | VAF 21/135 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.338); catalogued as rs779723221, COSV62620189, COSV62620254; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAAF4 | c.698G>A p.R233H | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs373052739; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FAM174A | c.524A>T p.D175V | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1280262056, COSV57062682; called by muse, mutect2, varscan2
- GJA1 | c.1075G>T p.V359L | Missense Mutation (SNP) | VAF 34/179 reads (19%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV56997697; called by muse, mutect2, varscan2
- HECTD4 | c.5399C>T p.A1800V | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs762298888, COSV66390331; called by muse, mutect2, varscan2
- HNRNPL | c.1621C>T p.R541C | Missense Mutation (SNP) | VAF 46/129 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.606); catalogued as COSV55492143; called by muse, mutect2, varscan2
- KANK2 | c.1217G>A p.S406N | Missense Mutation (SNP) | VAF 22/138 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.827); catalogued as COSV62007551; called by muse, mutect2, varscan2
- KLHL41 | c.1454G>A p.R485H | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs760007708, COSV52929456; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MAP7 | c.1443G>T p.R481S | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as COSV63418976; called by muse, mutect2, varscan2
- MUC16 | c.9294G>T p.Q3098H | Missense Mutation (SNP) | VAF 56/351 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.891); catalogued as rs752231032, COSV67460243; called by muse, mutect2
- NLRP4 | c.851C>T p.P284L | Missense Mutation (SNP) | VAF 31/178 reads (17%) | SIFT tolerated (0.75); PolyPhen possibly damaging (0.534); catalogued as rs768142392, COSV56712077; called by muse, mutect2, varscan2
- REPS1 | c.1337C>G p.P446R | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0.214); catalogued as COSV57810004; called by muse, mutect2, varscan2
- SCN3A | c.3617A>G p.N1206S | Missense Mutation (SNP) | VAF 46/193 reads (24%) | SIFT tolerated (0.81); PolyPhen possibly damaging (0.525); catalogued as COSV51807535; called by muse, mutect2, varscan2
- SMAD9 | c.1048G>A p.V350M (on ENST00000379826 / NM_001127217.3; = p.V313M on NM_005905.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.109); catalogued as rs757281925, COSV63204714; called by muse, mutect2, varscan2
- SPATA31D1 | c.1106C>G p.S369C | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.743); catalogued as COSV61194847, COSV61198741; called by muse, mutect2, varscan2
- STKLD1 | c.496A>T p.I166F | Missense Mutation (SNP) | VAF 89/450 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV64312243; called by muse, mutect2, varscan2
- TC2N | c.322G>A p.G108R | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV61746744; called by muse, mutect2, varscan2
- TESK2 | c.286G>A p.A96T | Missense Mutation (SNP) | VAF 77/176 reads (44%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.869); catalogued as rs1224190253, COSV59151254; called by muse, mutect2, varscan2
- TESMIN | c.1046C>T p.A349V | Missense Mutation (SNP) | VAF 64/363 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.896); catalogued as COSV54832316; called by muse, mutect2, varscan2
- TNRC6A | c.3019G>C p.A1007P | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59363185; called by muse, mutect2, varscan2
- VWA3B | c.3811C>T p.R1271* | Nonsense Mutation (SNP) | VAF 24/120 reads (20%) | catalogued as COSV71365667; called by muse, mutect2, varscan2
- ZFP57 | c.566A>T p.Y189F | Missense Mutation (SNP) | VAF 24/123 reads (20%) | SIFT tolerated (0.66); PolyPhen benign (0.013); catalogued as COSV65305982; called by muse, mutect2, varscan2
- ZNF20 | c.395C>T p.S132L | Missense Mutation (SNP) | VAF 66/318 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.079); catalogued as COSV61999142; called by muse, mutect2, varscan2
- ADAMTS14 | c.1236del p.N413Mfs*180 | Frame Shift Del (DEL) | VAF 18/103 reads (17%) | called by mutect2, pindel, varscan2
- CASKIN1 | c.3335del p.G1112Afs*31 | Frame Shift Del (DEL) | VAF 5/20 reads (25%) | called by mutect2, varscan2
- GFPT2 | c.959-3_959-2del p.X320_splice | Splice Site (DEL) | VAF 22/132 reads (17%) | called by mutect2, pindel
- R3HDM1 | c.698+3_698+6del p.X233_splice | Splice Site (DEL) | VAF 27/121 reads (22%) | called by mutect2, pindel, varscan2
- SBF2 | c.3701_3704dup p.Q1236Lfs*39 | Frame Shift Ins (INS) | VAF 33/151 reads (22%) | called by mutect2, pindel, varscan2
- SPOCK3 | c.592_593del p.K198Efs*5 | Frame Shift Del (DEL) | VAF 27/112 reads (24%) | called by mutect2, pindel, varscan2
- ANKRD17 | c.6279A>T p.P2093= | Silent (SNP) | VAF 53/200 reads (27%) | catalogued as COSV58218777; called by muse, mutect2, varscan2
- AP000311.1 | c.21C>T p.S7= | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as rs896967780, COSV51708293; called by muse, mutect2
- LRRC32 | c.738C>G p.T246= | Silent (SNP) | VAF 22/126 reads (17%) | catalogued as rs1378962279, COSV52632575; called by muse, mutect2, varscan2
- MAML2 | c.1176C>T p.S392= | Silent (SNP) | VAF 23/36 reads (64%) | catalogued as COSV73263210; called by muse, mutect2, varscan2
- PRDM9 | c.2490G>A p.K830= | Silent (SNP) | VAF 33/155 reads (21%) | catalogued as COSV57005286; called by muse, varscan2
- RARG | c.405C>T p.N135= | Silent (SNP) | VAF 31/158 reads (20%) | catalogued as COSV58432544; called by muse, mutect2, varscan2
- RSPH9 | c.30G>A p.L10= | Silent (SNP) | VAF 9/70 reads (13%) | catalogued as COSV64664679; called by muse, mutect2, varscan2
- TMEM132A | c.2394A>T p.A798= (on ENST00000453848 / NM_178031.3; = p.A799= on NM_017870.4) | Silent (SNP) | VAF 14/101 reads (14%) | catalogued as COSV50004149; called by muse, mutect2, varscan2
- TNRC6A | c.3018A>C p.S1006= | Silent (SNP) | VAF 24/87 reads (28%) | catalogued as COSV59363177; called by muse, mutect2, varscan2
- NACA | c.71-2115C>T | Intron (SNP) | VAF 11/56 reads (20%) | catalogued as COSV100771582; called by muse, mutect2, varscan2
- TMPRSS11F | c.1015+1774A>C | Intron (SNP) | VAF 90/197 reads (46%) | catalogued as COSV62465986; called by muse, mutect2, varscan2
